Somatic mutation profile of tumor specimen TCGA-D1-A15Z-01A (aliquot TCGA-D1-A15Z-01A-11D-A122-09) from TCGA case TCGA-D1-A15Z, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.9 years (26,638 days).
Specimen TCGA-D1-A15Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8608c8f3-7261-4621-9633-3c882fdd20a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A15Z-10A (Blood Derived Normal), aliquot TCGA-D1-A15Z-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/661a9716-f3e0-4875-bb0d-ced1ae17afd6

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 5, Frame Shift Del 5, In Frame Del 2, Frame Shift Ins 2, Splice Region 1, In Frame Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5429A>C p.D1810A | Missense Mutation (SNP) | VAF 134/317 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58615845, COSV58624974; called by muse, mutect2, varscan2
- F9 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | catalogued as rs137852227, CM166452, CM940433, COSV54378708; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 120/186 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.585dup p.H196Sfs*6 | Frame Shift Ins (INS) | VAF 88/381 reads (23%) | catalogued as rs786204901; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.50737C>T p.R16913* (on ENST00000591111; = p.R9489* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 65/148 reads (44%) | catalogued as rs1483931960, COSV59888643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC009779.3 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 188/431 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV57725136; called by muse, mutect2, varscan2
- ACAP1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 58/146 reads (40%) | catalogued as rs754562422, COSV50134121; called by muse, mutect2, varscan2
- ANKRD50 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs780417292, COSV72385060, COSV72386616; called by muse, mutect2, varscan2
- AXL | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774132867, COSV56563807; called by muse, mutect2, varscan2
- BMP1 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs774416710, COSV60476505; called by muse, mutect2, varscan2
- C3 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs780884558, COSV55568795; called by muse, mutect2, varscan2
- CALCOCO2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 106/195 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as COSV51951113, COSV99363741; called by muse, mutect2, varscan2
- CAMSAP2 | c.3793C>T p.R1265* (on ENST00000236925 / NM_001297707.2; = p.R1254* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 110/297 reads (37%) | catalogued as COSV52666995; called by muse, mutect2, varscan2
- CAPN2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs768082890, COSV54334084; called by muse, mutect2, varscan2
- CCDC39 | c.1961_1963del p.G654del | In Frame Del (DEL) | VAF 105/257 reads (41%) | catalogued as rs745993671; called by mutect2, pindel, varscan2
- CELSR3 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs1161884895, COSV50840241; called by muse, mutect2, varscan2
- CHRM2 | c.377C>A p.T126K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs757439767, COSV57765686; called by muse, mutect2, varscan2
- CSMD3 | c.3379G>T p.G1127C (on ENST00000297405 / NM_001363185.1; = p.G1023C on NM_052900.3) | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV52105540; called by muse, mutect2, varscan2
- DBH | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs151174779; called by muse, mutect2, varscan2
- EPB41L3 | c.3059C>T p.T1020M | Missense Mutation (SNP) | VAF 157/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527461275, COSV59444888; called by muse, mutect2, varscan2
- FAT3 | c.2159G>T p.R720I | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV53076958, COSV53113948; called by muse, mutect2, varscan2
- GAD2 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 163/564 reads (29%) | catalogued as rs897876627, COSV52150849; called by muse, mutect2, varscan2
- GNG8 | c.157del p.V53Yfs*? | Frame Shift Del (DEL) | VAF 54/133 reads (41%) | catalogued as COSV56257629; called by mutect2, pindel, varscan2
- GRIK3 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs746478247, COSV66135600, COSV66143041; called by muse, mutect2, varscan2
- GYPA | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV51620035; called by muse, mutect2, varscan2
- HTR3C | c.991T>C p.Y331H | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.06); catalogued as rs567421103, COSV59174316; called by muse, mutect2, varscan2
- ITLN1 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1191229614, COSV58273859; called by muse, mutect2, varscan2
- KCNJ11 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769283457, COSV56846454; called by muse, mutect2, varscan2
- LIN7C | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1275696603, COSV53414612; called by muse, mutect2, varscan2
- MIEF2 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59901408; called by muse, mutect2, varscan2
- MORC1 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 137/335 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs368059488; called by muse, mutect2, varscan2
- NOL4L | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV62889089; called by muse, mutect2, varscan2
- NSD1 | c.4603C>T p.R1535C | Missense Mutation (SNP) | VAF 126/271 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61770969; called by muse, mutect2, varscan2
- NUP214 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV63907652; called by muse, mutect2, varscan2
- OR8K3 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 109/217 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as rs780800705, COSV57130779; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.971C>T p.S324F (on ENST00000259318 / NM_001136562.3; = p.S555F on NM_007203.5) | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs367791261; called by muse, mutect2, varscan2
- PGAP3 | c.280-2del p.X94_splice | Splice Site (DEL) | VAF 25/75 reads (33%) | catalogued as COSV56130217; called by mutect2, pindel, varscan2
- PGLYRP3 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs748288161, COSV51948890; called by muse, mutect2, varscan2
- PSMD10 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV54263711; called by muse, mutect2, varscan2
- PYGB | c.1196G>C p.R399P | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53815772; called by muse, mutect2, varscan2
- RBM25 | c.1661G>C p.G554A | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56198608; called by muse, mutect2, varscan2
- RIMS2 | c.3346G>A p.D1116N (on ENST00000666250 / NM_001348490.2; = p.D924N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV51653992; called by muse, mutect2, varscan2
- SH3TC2 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs530824367, COSV60460848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A14 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1369169484, COSV61585566; called by muse, mutect2, varscan2
- SOCS7 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 171/412 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.179); catalogued as rs752535505; called by muse, mutect2, varscan2
- SPACA3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.817); catalogued as rs1487806532, COSV52190299; called by muse, mutect2, varscan2
- SYNPO2L | c.2588G>A p.C863Y (on ENST00000394810 / NM_001114133.3; = p.C639Y on NM_024875.5) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV65736089; called by muse, mutect2, varscan2
- SZT2 | c.6289C>A p.R2097= (on ENST00000634258 / NM_001365999.1; = p.R2040= on NM_015284.4) | Splice Region (SNP) | VAF 77/178 reads (43%) | catalogued as COSV65167250; called by muse, mutect2, varscan2
- TBC1D31 | c.547del p.I183Sfs*40 | Frame Shift Del (DEL) | VAF 105/282 reads (37%) | catalogued as COSV54863825, COSV54868082; called by mutect2, pindel, varscan2
- TENM2 | c.7932G>C p.E2644D (on ENST00000518659 / NM_001122679.2; = p.E2405D on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV69122818; called by muse, mutect2, varscan2
- TLR2 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1411329660, COSV52605008; called by muse, mutect2, varscan2
- TPM4 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61208598; called by muse, mutect2, varscan2
- USP26 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192465138, COSV63708068; called by muse, mutect2, varscan2
- WDR90 | c.1754T>C p.I585T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs576751240, COSV53466431; called by muse, mutect2, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 59/158 reads (37%) | catalogued as rs774038489; called by mutect2, pindel, varscan2
- BPIFB2 | c.205_209dup p.I71Sfs*4 | Frame Shift Ins (INS) | VAF 93/219 reads (42%) | called by mutect2, pindel, varscan2
- DICER1 | c.1616del p.L539Cfs*23 | Frame Shift Del (DEL) | VAF 103/253 reads (41%) | called by mutect2, pindel, varscan2
- PTEN | c.779_780del p.K260Tfs*37 | Frame Shift Del (DEL) | VAF 185/345 reads (54%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.3634_3636del p.E1212del | In Frame Del (DEL) | VAF 18/52 reads (35%) | called by pindel, varscan2
- SMYD2 | c.704_705+1dup | In Frame Ins (INS) | VAF 35/253 reads (14%) | called by mutect2, varscan2
- A1BG | c.735C>T p.R245= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs374586221; called by muse, mutect2, varscan2
- ADRA1D | c.1002C>T p.S334= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs370636418, COSV65240239; called by muse, mutect2, varscan2
- ANAPC2 | c.1941C>T p.D647= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs763876082, COSV60568549; called by muse, mutect2, varscan2
- BIRC7 | c.843G>T p.L281= (on ENST00000217169 / NM_139317.3; = p.L263= on NM_022161.4) | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV53900283; called by muse, mutect2, varscan2
- CRACDL | c.1272G>A p.A424= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV67406553; called by muse, mutect2, varscan2
- DIO3 | c.387G>A p.A129= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs376085567, COSV63773013; called by muse, mutect2, varscan2
- ESRRG | c.294G>A p.R98= | Silent (SNP) | VAF 140/294 reads (48%) | catalogued as rs1357962607, COSV63150300; called by muse, mutect2, varscan2
- KALRN | c.1887C>T p.F629= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as rs566946896, COSV53753260; called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2
- KRT23 | c.1104C>A p.I368= | Silent (SNP) | VAF 189/454 reads (42%) | catalogued as COSV52927029; called by muse, mutect2, varscan2
- KRT82 | c.609C>A p.G203= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57785381; called by muse, mutect2
- MUC5B | c.10755C>T p.Y3585= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as COSV71590089; called by muse, mutect2, varscan2
- MYO5B | c.5043A>C p.V1681= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as COSV53211554; called by muse, mutect2
- NLRP11 | c.672C>T p.L224= | Silent (SNP) | VAF 95/226 reads (42%) | catalogued as COSV64085711; called by muse, mutect2, varscan2
- OR4D10 | c.291C>T p.C97= | Silent (SNP) | VAF 92/223 reads (41%) | catalogued as COSV101597005, COSV73259967; called by muse, mutect2, varscan2
- PPP2R2B | c.855G>A p.S285= (on ENST00000394409; = p.S351= on NM_181674.2) | Silent (SNP) | VAF 129/332 reads (39%) | catalogued as rs772927479, COSV60753716; called by muse, mutect2, varscan2
- SLC4A4 | c.351C>T p.A117= (on ENST00000264485 / NM_001098484.3; = p.A73= on NM_003759.4) | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs773602702, COSV52615208, COSV52625933; called by muse, mutect2, varscan2
- SRPRA | c.1056G>A p.K352= | Silent (SNP) | VAF 122/271 reads (45%) | catalogued as COSV55005222; called by muse, mutect2, varscan2
- VGLL1 | c.688+64A>T | Intron (SNP) | VAF 15/350 reads (4%) | catalogued as COSV65702917; called by muse, mutect2
